Somatic mutation profile of tumor specimen TCGA-CS-6666-01A (aliquot TCGA-CS-6666-01A-11D-1893-08) from TCGA case TCGA-CS-6666, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 22.8 years (8,340 days).
Specimen TCGA-CS-6666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c69dd810-98b8-4623-b105-f2f7b4cbb3d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6666-10A (Blood Derived Normal), aliquot TCGA-CS-6666-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63e56c46-bcce-4e8d-8ce2-5cfeaf2848e1

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 26, Silent 4, Nonstop Mutation 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 51/126 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 50/96 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, varscan2
- AGPAT3 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs774081698, COSV52373155; called by mutect2, varscan2
- BTNL2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV66631594; called by muse, mutect2, varscan2
- CARMIL1 | c.3794G>C p.S1265T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV61521944; called by muse, mutect2, varscan2
- CLIC1 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV65384297; called by muse, mutect2, varscan2
- CMIP | c.343G>T p.E115* (on ENST00000537098 / NM_198390.2; = p.E21* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 11/238 reads (5%) | catalogued as COSV73345159; called by muse, mutect2
- CTSO | c.965G>C p.*322Sext*12 | Nonstop Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV70809482; called by muse, mutect2, varscan2
- DCC | c.4102T>C p.S1368P | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV71438375; called by muse, mutect2, varscan2
- DNAH5 | c.9721G>C p.V3241L | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV54243434; called by muse, mutect2, varscan2
- DSCAM | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs201680585, COSV101259722; called by muse, mutect2, varscan2
- DYNC1I2 | c.1445T>C p.I482T | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1210751424, COSV55528615; called by muse, mutect2
- FSIP2 | c.16174T>C p.F5392L | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100555891; called by muse, mutect2
- KIAA0825 | c.713A>C p.D238A | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV56957376; called by muse, mutect2
- KRT33A | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs148488457; called by muse, mutect2
- KRT33B | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs750809007, COSV52440042; called by muse, mutect2
- MAB21L2 | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58262952; called by muse, mutect2, varscan2
- NBEAL1 | c.4719G>C p.Q1573H | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV71375186; called by muse, mutect2
- NDUFS1 | c.1972G>C p.D658H | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV51912480; called by muse, mutect2
- PLAA | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV68305417; called by muse, mutect2
- PTPN14 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.9); catalogued as COSV65286701; called by muse, mutect2
- PTPRB | c.2273A>C p.D758A | Missense Mutation (SNP) | VAF 9/299 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV99718494; called by muse, mutect2
- PURG | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV53304831; called by muse, mutect2, varscan2
- REL | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV54365658, COSV54366253; called by muse, mutect2, varscan2
- TAS2R4 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV56093984; called by muse, mutect2
- VIL1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs372157130; called by muse, mutect2, varscan2
- ZNF800 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56179811, COSV99758099; called by muse, mutect2
- ATRX | c.3953dup p.N1318Kfs*6 | Frame Shift Ins (INS) | VAF 20/30 reads (67%) | called by mutect2, pindel, varscan2
- ABCB1 | c.987A>G p.G329= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV55959269; called by muse, mutect2, varscan2
- CLMP | c.480G>A p.E160= | Silent (SNP) | VAF 6/137 reads (4%) | catalogued as COSV71650636; called by muse, mutect2
- ENPP5 | c.1140C>T p.L380= | Silent (SNP) | VAF 30/401 reads (7%) | catalogued as COSV57909589; called by muse, mutect2
- TMPRSS2 | c.882C>T p.A294= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs562033822, COSV59821683; called by muse, mutect2, varscan2
